Gene-level copy-number profile of tumor specimen TCGA-30-1855-01A from TCGA case TCGA-30-1855, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.3 years (22,394 days).
Specimen TCGA-30-1855-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.de79be76-863b-4c72-ad38-06d081b65984.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1855-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/34d30f53-5c6f-4fe1-8276-e5871bb87b9a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,310; copy number 2: 20,378; copy number 3: 20,476; copy number 4: 9,917; copy number 5: 2,228; copy number 6: 157; copy number 7: 334; copy number 8: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-30-1855-01A-01D-0577-01): tumor purity 0.7, ploidy 2.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,727 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,043,829–44,390,823, 212 genes, copy number 5–6 (broad region; genes not listed).
- chr1:46,040,140–46,967,874, 34 genes, copy number 5: PIK3R3, P3R3URF-PIK3R3, AL358075.1, AL358075.3, AL358075.2, TSPAN1, P3R3URF, POMGNT1, LURAP1, RAD54L, LRRC41, UQCRH, NSUN4, AL122001.1, FAAH, FAAHP1, LINC01398, DMBX1, TMEM275, MKNK1-AS1, KNCN, MKNK1, MOB3C, ATPAF1, NENFP1, TEX38, EFCAB14-AS1, EFCAB14, AL593856.1, CYP4B1, CYP4Z2P, TUBAP8, CYP4A11, CYP4A26P.
- chr1:174,996,524–182,314,061, 126 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:228,208,044–228,378,876, 1 gene, copy number 5 (within-gene range 4–5): OBSCN.
- chr1:228,295,549–239,250,818, 255 genes, copy number 5 (broad region; genes not listed).
- chr2:118,766,965–118,994,660, 4 genes, copy number 5: LINC01956, EN1, MARCO, AC013457.1.
- chr3:161,600,438–186,772,986, 384 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:37,939,365–38,465,480, 8 genes, copy number 8 (within-gene range 4–8): AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3.
- chr8:54,330,687–54,871,720, 10 genes, copy number 5 (within-gene range 2–5): RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7, RP1, SEC11B, AC090151.1.
- chr8:121,612,116–145,066,685, 446 genes, copy number 5–7 (broad region; genes not listed).
- chr11:56,542,262–79,441,030, 994 genes, copy number 5 (broad region; genes not listed).
- chr12:11,649,674–11,895,377, 1 gene, copy number 5 (within-gene range 2–5): ETV6.
- chr12:12,111,163–12,112,036, 2 genes, copy number 5: PTMAP9, MIR1244-4.
- chr12:23,529,504–27,806,390, 86 genes, copy number 5–7 (broad region; genes not listed).
- chr16:46,469,341–49,857,919, 83 genes, copy number 7 (broad region; genes not listed).
- chr16:82,434,828–84,145,192, 29 genes, copy number 6: AC009117.1, AC009117.2, CDH13, MIR8058, AC099506.2, AC099506.1, AC099506.3, RN7SL134P, AC125793.1, AC009142.1, MIR3182, AC009063.3, AC009063.4, AC009063.2, AC009063.1, AC009119.1, HSBP1, MLYCD, AC009119.2, OSGIN1, NECAB2, SLC38A8, RNA5SP432, AC040169.4, MBTPS1, AC040169.3, AC040169.1, AC040169.2, HSDL1.
- chr17:75,236,599–75,856,507, 33 genes, copy number 6 (within-gene range 3–6): GGA3, MRPS7, MIF4GD, AC022211.2, SLC25A19, GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738, UNK, AC087289.1, UNC13D, WBP2.
- chr19:29,489,775–30,085,893, 19 genes, copy number 5: AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.

Autosomal genes at a single copy (total copy number 1): 4,571. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
